Somatic mutation profile of tumor specimen TCGA-06-0210-02A (aliquot TCGA-06-0210-02A-01D-2280-08) from TCGA case TCGA-06-0210, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.8 years (26,600 days).
Specimen TCGA-06-0210-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53e6252e-0f66-454b-8094-f232ccf3b940.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0210-10A (Blood Derived Normal), aliquot TCGA-06-0210-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19b1ff0f-51f4-4719-9a05-532424ed9dcf

The open-access MAF lists 68 somatic variants for this specimen: 53 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 12, Nonsense Mutation 3, Intron 2, Splice Site 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs121964878, CM034217, COSV55730231; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HEXA | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121907957, CM920330, COSV51507319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 36/82 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 61/102 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTL9 | c.1138G>A p.V380I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs532021673, COSV61005106; called by muse, mutect2, varscan2
- ADCY1 | c.1912C>G p.L638V | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV52043265; called by muse, mutect2, varscan2
- ARFGAP2 | c.305C>G p.A102G | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as COSV54068072; called by muse, mutect2, varscan2
- ARHGEF28 | c.913A>G p.I305V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1260665167, COSV55271556; called by muse, varscan2
- ATP2B3 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs200641356, COSV54848455; called by muse, mutect2, varscan2
- BFSP1 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as rs577981820, COSV64899369; called by muse, mutect2, varscan2
- CAMSAP2 | c.616C>G p.H206D | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV52671219; called by muse, mutect2, varscan2
- CHD5 | c.3458C>T p.S1153L | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1351642953, COSV52415446; called by muse, mutect2, varscan2
- CPNE8 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs926258147, COSV58838522; called by muse, mutect2, varscan2
- CPZ | c.647G>A p.S216N (on ENST00000360986 / NM_001014447.3; = p.S205N on NM_003652.3) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1198416310, COSV59926275, COSV59926457, COSV59926554; called by muse, mutect2, varscan2
- CTNNA2 | c.203C>G p.T68S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV100781182, COSV63570327; called by muse, mutect2, varscan2
- DNAJC6 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs761817101, COSV54775600; called by muse, mutect2, varscan2
- DSG2 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs375422019, COSV55199493; called by muse, mutect2, varscan2
- F5 | c.1976-2A>C p.X659_splice | Splice Site (SNP) | VAF 21/58 reads (36%) | catalogued as COSV63122920, COSV63124448; called by muse, mutect2, varscan2
- FGD1 | c.422C>A p.T141N | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.134); catalogued as COSV64308781; called by muse, mutect2, varscan2
- FKBP6 | c.697G>C p.D233H | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV52720128, COSV52720387; called by muse, mutect2, varscan2
- GCK | c.962C>G p.S321C | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV60788282; called by muse, mutect2, varscan2
- GFRAL | c.194A>G p.Y65C | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as rs1475878119, COSV61235918; called by muse, mutect2, varscan2
- INHBA | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54219953; called by muse, mutect2, varscan2
- KASH5 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71358030; called by muse, mutect2, varscan2
- KIF26A | c.3884G>A p.R1295H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV59470954; called by muse, mutect2, varscan2
- MS4A1 | c.569T>A p.F190Y | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.394); catalogued as COSV61942160; called by muse, mutect2, varscan2
- MUC3A | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated, low confidence (0.17); catalogued as rs781659697, COSV60212876; called by muse, mutect2, varscan2
- OR52R1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as rs200440576; called by muse, mutect2, varscan2
- PCDHGB3 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 11/245 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as COSV54042465; called by muse, mutect2
- PCSK2 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1199393951, COSV52733336; called by muse, mutect2, varscan2
- PRDM9 | c.2483G>T p.G828V | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57013266, COSV57013946; called by muse, varscan2
- PRPF38A | c.804C>G p.S268R | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.985); catalogued as COSV57123398; called by muse, mutect2, varscan2
- REPIN1 | c.1466G>T p.C489F | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68292287, COSV68292360; called by muse, mutect2, varscan2
- REPS2 | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58188699; called by muse, mutect2, varscan2
- RNF17 | c.4172C>T p.S1391L | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747304860, COSV55041145; called by muse, mutect2, varscan2
- RYR1 | c.14911A>G p.T4971A | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs756040490, COSV62112186; called by muse, mutect2, varscan2
- SEMA3F | c.425G>T p.C142F | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50037126; called by muse, mutect2, varscan2
- SERPINA3 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV67586813; called by muse, mutect2, varscan2
- SLC30A3 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1343110597, COSV51988244; called by muse, mutect2, varscan2
- SPAG7 | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.196); catalogued as COSV99236889; called by muse, mutect2
- SPTA1 | c.2671C>T p.R891* | Nonsense Mutation (SNP) | VAF 105/243 reads (43%) | catalogued as rs755630903, CM148356, COSV63749670; called by muse, mutect2, varscan2
- STXBP5L | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | catalogued as rs1388311069, COSV56523458; called by muse, mutect2, varscan2
- TMC4 | c.1236G>T p.K412N (on ENST00000617472 / NM_001145303.3; = p.K406N on NM_144686.4) | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV55827311; called by muse, mutect2, varscan2
- TNN | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316855469, COSV53436684, COSV99513658; called by muse, mutect2, varscan2
- VPS50 | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.956); catalogued as rs769084619, COSV52495042; called by muse, mutect2, varscan2
- ZNF483 | c.1013C>G p.P338R | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV58515814; called by muse, mutect2, varscan2
- ZNF570 | c.1247G>T p.C416F | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57579047; called by muse, mutect2, varscan2
- ARID1A | c.2876C>A p.A959E | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- F9 | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- IGKV1D-16 | c.223A>T p.S75C | Missense Mutation (SNP) | VAF 73/232 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- PCDHGA2 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- TENM3 | c.469del p.L157* | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- TEX11 | c.2508T>A p.C836* (on ENST00000344304; = p.C821* on NM_031276.3) | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | called by muse, varscan2
- CASK | c.6C>T p.A2= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV59367194; called by muse, mutect2, varscan2
- CD46 | c.351C>T p.Y117= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs999821608, COSV59731619, COSV59735746; called by muse, mutect2, varscan2
- HCAR1 | c.384C>T p.S128= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV63674676; called by muse, mutect2, varscan2
- LCK | c.486G>A p.S162= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as rs1126767; called by muse, mutect2, varscan2
- LRWD1 | c.409C>T p.L137= | Silent (SNP) | VAF 47/162 reads (29%) | catalogued as rs1563653319, COSV52962392; called by muse, mutect2, varscan2
- PPP1R3B | c.495G>A p.T165= | Silent (SNP) | VAF 68/190 reads (36%) | catalogued as rs138887555; called by muse, mutect2, varscan2
- SLC22A1 | c.1557C>T p.V519= | Silent (SNP) | VAF 47/238 reads (20%) | catalogued as rs543955963, COSV100267011; called by muse, mutect2, varscan2
- SPTA1 | c.3645G>C p.L1215= | Silent (SNP) | VAF 37/123 reads (30%) | catalogued as COSV63760296; called by muse, mutect2, varscan2
- STAB1 | c.4707C>T p.C1569= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs375629208; called by muse, mutect2, varscan2
- THSD7A | c.2925A>T p.P975= | Silent (SNP) | VAF 65/254 reads (26%) | catalogued as rs79441692, COSV70273650; called by muse, mutect2, varscan2
- VWF | c.5247G>A p.P1749= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs764884764, COSV54618993; called by muse, mutect2, varscan2
- ZFYVE27 | c.1062G>A p.S354= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as rs756798085, COSV61746506; called by muse, mutect2, varscan2
- CCDC33 | c.2139+76G>A | Intron (SNP) | VAF 25/68 reads (37%) | catalogued as COSV51432317; called by muse, mutect2, varscan2
- CXorf56 | c.243-997C>T | Intron (SNP) | VAF 110/292 reads (38%) | catalogued as COSV57438483; called by muse, mutect2, varscan2
- ZNF271P | n.1012T>G | RNA (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
